Gene-level copy-number profile of tumor specimen TCGA-09-1659-01B from TCGA case TCGA-09-1659, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 51.3 years (18,733 days).
Specimen TCGA-09-1659-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.a3ec404c-0806-48eb-b3ac-2a5e759748b1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-09-1659-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cc1b5b0a-a9eb-4c06-9b37-0fc305872efa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 4,027; copy number 2: 29,067; copy number 3: 20,057; copy number 4: 5,898; copy number 5: 448; copy number 6: 59; copy number 7: 77; copy number 8: 165; copy number 9: 3; copy number 11: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-09-1659-01): tumor purity 0.87, ploidy 2.56, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 754 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:102,763,322–106,544,744, 28 genes, copy number 6: AC099567.1, COL11A1, SOD2P1, AC095032.2, AC095032.1, RN7SKP285, RNPC3, AMY2B, ACTG1P4, AMY2A, AMY1A, AC105272.1, AMY1B, AMYP1, AMY1C, AL136455.1, AC092506.1, FTLP17, AL591888.1, CDK4P1, LINC01676, SEPTIN2P1, AL512844.2, AL512844.1, LINC01677, AL355306.2, AL355306.1, AL499605.1.
- chr3:52,455,118–56,468,467, 73 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr5:50,396,192–53,881,051, 47 genes, copy number 5: EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC027329.1, AC108114.1, FST, NDUFS4, LINC02105, ASS1P9, AC025175.1.
- chr5:53,897,464–53,951,599, 3 genes, copy number 5: AC025175.2, RNU6-272P, MIR581.
- chr6:31,580,525–32,003,521, 61 genes, copy number 5 (broad region; genes not listed).
- chr6:82,263,996–82,367,420, 3 genes, copy number 9: AL121977.1, AL121977.2, TPBG.
- chr6:92,387,841–92,633,268, 2 genes, copy number 11: AL133457.1, AL359987.1.
- chr8:119,833,976–119,855,894, 1 gene, copy number 5 (within-gene range 4–5): DSCC1.
- chr8:119,862,662–120,373,573, 6 genes, copy number 5 (within-gene range 4–5): RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1, COL14A1.
- chr9:122,788,933–123,930,152, 26 genes, copy number 6 (within-gene range 2–6): OR5C1, PDCL, OR1K1, KRT18P67, RC3H2, SNORD90, ZBTB6, ZBTB26, AC007066.2, AC007066.3, RABGAP1, RNY1P15, AC007066.1, GPR21, AL365338.1, MIR600HG, STRBP, MIR600, CRB2, DENND1A, MIR601, MIR7150, AL445489.1, AL390774.2, AL390774.1, PIGFP2.
- chr10:77,350,851–77,587,159, 3 genes, copy number 5: KCNMA1-AS3, COX6CP15, RNA5SP321.
- chr14:20,897,985–22,482,959, 114 genes, copy number 5–8 (within-gene range 1–8) (broad region; genes not listed).
- chr15:63,276,018–63,602,428, 8 genes, copy number 7: APH1B, CA12, LINC02568, AC007950.1, AC007950.2, USP3, USP3-AS1, FBXL22.
- chr16:69,463,844–69,975,344, 15 genes, copy number 5: AC026464.2, NFAT5, MIR1538, AC009032.1, AC012321.1, NQO1, AC092115.2, AC092115.3, NOB1, AC092115.1, WWP2, SNORA62, MIR140, CLEC18A, AC026468.1.
- chr16:69,976,388–69,996,188, 1 gene, copy number 5 (within-gene range 2–5): NPIPB14P.
- chr17:41,609,778–41,836,260, 13 genes, copy number 5: KRT16, KRT17, KRT42P, AC130686.1, EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B.
- chr17:48,528,526–50,215,922, 103 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr17:59,331,655–59,526,946, 5 genes, copy number 6 (within-gene range 3–6): YPEL2, AC091059.2, MIR4729, AC091059.1, LINC01476.
- chr17:75,031,097–76,121,576, 69 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr19:17,601,328–17,688,365, 1 gene, copy number 5 (within-gene range 3–5): UNC13A.
- chr19:17,622,447–19,273,369, 85 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr19:27,638,483–30,957,192, 69 genes, copy number 7 (broad region; genes not listed).
- chr20:57,266,797–57,712,780, 18 genes, copy number 5: AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, AL109955.1, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA.

Autosomal genes at a single copy (total copy number 1): 2,316. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
